Gene-level copy-number profile of tumor specimen C3L-01606-01 from CPTAC case C3L-01606, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 66.7 years (24,376 days).
Specimen C3L-01606-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2ebe4804-77a8-42fa-ae91-8e1382a54d79.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01606-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/7c4dbc54-ec5f-4765-909d-aca80958c161

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 15,029; copy number 2: 40,297; copy number 3: 2,715; copy number 4: 629; copy number 5: 9; copy number 7: 130; copy number 8: 57.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,175,528–4,175,899, 1 gene: EEF1DP6.
- chr2:130,073,535–130,139,417, 5 genes (within-gene range 0–2): POTEF, AC018865.1, POTEF-AS1, RNU6-1049P, MED15P9.
- chr8:12,628,476–12,756,073, 10 genes: RPS3AP35, AC068587.3, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2.
- chr21:7,744,962–8,603,984, 27 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 196 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,862,123–43,674,591, 187 genes, copy number 7–8 (broad region; genes not listed).
- chr15:30,344,307–30,420,429, 9 genes, copy number 5: AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2.

Autosomal genes at a single copy (total copy number 1): 12,709. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
